Somatic mutation profile of tumor specimen MP2PRT-PARPJK-TMP1-A (aliquot MP2PRT-PARPJK-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PARPJK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.7 years (613 days).
Specimen MP2PRT-PARPJK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 87a51cdc-23cf-4bcd-817f-571831fc1e33.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARPJK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARPJK-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a584c7a6-0e26-483c-b122-90c13fd27f2a

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, Nonsense Mutation 2, 5'Flank 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 29/393 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- PTPN11 | c.172A>T p.N58Y | Missense Mutation (SNP) | VAF 83/329 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as rs397507505, CM044250, CM060441, COSV61007800; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CAND1 | c.3448C>T p.R1150C | Missense Mutation (SNP) | VAF 62/244 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs764897319; called by muse, mutect2, varscan2
- CTBP1 | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 36/860 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52076667; called by muse, mutect2
- EHBP1L1 | c.3646C>T p.R1216C | Missense Mutation (SNP) | VAF 57/662 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1398121404; called by muse, mutect2
- ASPHD1 | c.565C>A p.L189M | Missense Mutation (SNP) | VAF 67/536 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- CCDC144A | c.3343C>A p.Q1115K | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by mutect2, varscan2
- CDH26 | c.1849G>T p.A617S | Missense Mutation (SNP) | VAF 24/464 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.06); called by muse, mutect2
- IFT27 | c.190G>T p.D64Y (on ENST00000433985 / NM_001363003.2; = p.D63Y on NM_006860.5) | Missense Mutation (SNP) | VAF 72/332 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHV4-59 | c.349_350insGTA | In Frame Ins (INS) | VAF 82/314 reads (26%) | called by mutect2, pindel*, varscan2*
- KIF27 | c.2466A>C p.Q822H | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PRRG1 | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 83/410 reads (20%) | called by muse, mutect2, varscan2
- SNX18 | c.1392T>A p.Y464* | Nonsense Mutation (SNP) | VAF 149/536 reads (28%) | called by muse, mutect2, varscan2
- TRIOBP | c.4883G>A p.S1628N | Missense Mutation (SNP) | VAF 214/614 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- XIAP | c.806T>A p.I269N | Missense Mutation (SNP) | VAF 34/555 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- CELA2A | c.12G>A p.T4= | Silent (SNP) | VAF 44/448 reads (10%) | catalogued as rs368746546, COSV62748293; called by muse, mutect2
- RIMS1 | c.1206G>A p.A402= | Silent (SNP) | VAF 47/975 reads (5%) | catalogued as rs1372880377; called by muse, mutect2
- TMPRSS6 | c.477C>T p.P159= | Silent (SNP) | VAF 33/565 reads (6%) | catalogued as rs182120673; called by muse, mutect2
- C4orf50 | chr4:5992916 C>T | 5'Flank (SNP) | VAF 19/628 reads (3%) | called by muse, mutect2
